Somatic mutation profile of tumor specimen C3L-05867-54 (aliquot CPT0370770002) from CPTAC case C3L-05867, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 37.1 years (13,536 days).
Specimen C3L-05867-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28091c6b-2171-4be9-8b00-544be9e91a4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05867-50 (Buccal Cell Normal), aliquot CPT0370740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54d14288-8314-45a3-81c4-a8be619b284a

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TYR | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.773); catalogued as rs63159160, CD941801, CM920693, CM971545, CP044544; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ARHGEF2 | c.289G>A p.A97T (on ENST00000361247 / NM_001162383.2; = p.A70T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1299252651; called by muse, mutect2, varscan2
- BAHCC1 | c.2550dup p.G851Rfs*223 | Frame Shift Ins (INS) | VAF 37/99 reads (37%) | catalogued as rs1555653824; called by mutect2, varscan2
- NPM1 | c.847-4_859delinsTCCAGGCTATTCAAGATCTCTG p.X283_splice | Splice Site (INS) | VAF 5/59 reads (8%) | called by pindel, varscan2*
- ACTG1P17 | n.935T>C | RNA (SNP) | VAF 130/280 reads (46%) | catalogued as rs1186619566; called by mutect2, varscan2
- MAST4 | c.674+59298G>A | Intron (SNP) | VAF 98/242 reads (40%) | catalogued as rs767263959, COSV101282628; called by muse, mutect2, varscan2
